Somatic mutation profile of tumor specimen TCGA-20-1684-01A (aliquot TCGA-20-1684-01A-01W-0633-09) from TCGA case TCGA-20-1684, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.3 years (18,755 days).
Specimen TCGA-20-1684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94d1fd78-3e56-4520-8298-683ddc315687.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-20-1684-10A (Blood Derived Normal), aliquot TCGA-20-1684-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b33eaac-c9e0-4b5f-8231-f430d9d58040

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, Nonsense Mutation 5, Frame Shift Ins 3, In Frame Del 1, Intron 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH15 | c.2785C>T p.R929* | Nonsense Mutation (SNP) | VAF 54/54 reads (100%) | catalogued as rs1057516342, CM050735, COSV57337854; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTL6B | c.695dup p.N233Kfs*17 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as rs779550102; called by mutect2, varscan2
- ATP2B2 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59500061; called by muse, mutect2, varscan2
- ATXN7 | c.2315A>G p.H772R | Missense Mutation (SNP) | VAF 124/312 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.084); catalogued as rs775575707, COSV55752525; called by muse, varscan2
- CATSPER2 | c.1403G>A p.W468* (on ENST00000321596 / NM_001282309.3; = p.W470* on NM_172095.4) | Nonsense Mutation (SNP) | VAF 94/299 reads (31%) | catalogued as COSV100390618, COSV58661172; called by muse, mutect2, varscan2
- CDH11 | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 420/699 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51765296; called by muse, mutect2, varscan2
- CFH | c.729C>A p.Y243* | Nonsense Mutation (SNP) | VAF 25/273 reads (9%) | catalogued as COSV100661359; called by muse, mutect2
- CLEC3A | c.144C>A p.D48E (on ENST00000651443; = p.D39E on NM_005752.6) | Missense Mutation (SNP) | VAF 122/349 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199500922; called by muse, mutect2, varscan2
- DCHS1 | c.6761G>T p.S2254I | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); catalogued as COSV55038014; called by muse, mutect2, varscan2
- ENO2 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as COSV50390759; called by muse, mutect2, varscan2
- EPHA5 | c.1729G>C p.V577L | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV99897328; called by muse, mutect2
- FAM102B | c.233G>T p.C78F | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64240321; called by muse, mutect2, varscan2
- FANCF | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59416514; called by muse, mutect2, varscan2
- FXR1 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 272/531 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV59764017; called by muse, mutect2, varscan2
- H2BC5 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV56800630, COSV56801968; called by muse, mutect2, varscan2
- ITPRID2 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57473246; called by muse, mutect2, varscan2
- LDLR | c.2126G>C p.R709T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as CM151103, COSV52944134; called by muse, mutect2, varscan2
- PNISR | c.1102+1G>A p.X368_splice | Splice Site (SNP) | VAF 28/137 reads (20%) | catalogued as COSV65079868; called by muse, mutect2, varscan2
- RINT1 | c.966A>C p.R322S | Missense Mutation (SNP) | VAF 94/337 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV57559164; called by muse, mutect2, varscan2
- SCN2A | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV51841311; called by muse, mutect2, varscan2
- SLC32A1 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1483624176, COSV54147268; called by muse, mutect2, varscan2
- THAP4 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs1239498980, COSV101126009; called by muse, mutect2, varscan2
- TP53 | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 131/137 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525465, COSV52750141, COSV52756133, COSV52784543, COSV52863408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 129/136 reads (95%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.936); catalogued as COSV52783299, COSV52873550, COSV52906834; called by muse, mutect2, varscan2
- ZADH2 | c.550G>T p.G184* | Nonsense Mutation (SNP) | VAF 10/188 reads (5%) | catalogued as COSV100463339; called by muse, mutect2
- ZNF565 | c.220G>T p.V74L (on ENST00000355114; = p.V34L on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 361/555 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58411094, COSV58411151; called by muse, mutect2, varscan2
- CDK12 | c.2353dup p.S785Kfs*4 | Frame Shift Ins (INS) | VAF 68/97 reads (70%) | called by mutect2, pindel, varscan2
- HIPK1 | c.654_659del p.K219_I220del | In Frame Del (DEL) | VAF 118/377 reads (31%) | called by mutect2, pindel, varscan2
- IGKV1D-17 | c.295A>T p.S99C | Missense Mutation (SNP) | VAF 108/671 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TPRKB | c.208dup p.M70Nfs*9 | Frame Shift Ins (INS) | VAF 52/274 reads (19%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.3393C>T p.T1131= | Silent (SNP) | VAF 761/840 reads (91%) | catalogued as COSV54960073; called by muse, mutect2, varscan2
- CACNG4 | c.777G>A p.S259= | Silent (SNP) | VAF 235/243 reads (97%) | catalogued as rs375384748; called by muse, mutect2, varscan2
- CDX4 | c.138G>A p.A46= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as rs757822096, COSV65171721; called by muse, mutect2, varscan2
- GALNT5 | c.1092T>C p.S364= | Silent (SNP) | VAF 44/784 reads (6%) | catalogued as COSV99374967; called by muse, mutect2
- IGHG2 | c.549C>T p.S183= | Silent (SNP) | VAF 23/649 reads (4%) | catalogued as rs369072934; called by muse, mutect2
- MX2 | c.894A>T p.L298= | Silent (SNP) | VAF 56/105 reads (53%) | catalogued as COSV58097284; called by muse, mutect2, varscan2
- NLRP12 | c.2031C>T p.R677= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as rs747097064, COSV60749691; called by muse, mutect2, varscan2
- PTPRZ1 | c.3741G>A p.S1247= | Silent (SNP) | VAF 120/631 reads (19%) | catalogued as rs145804208; called by muse, mutect2, varscan2
- RPAP1 | c.2082C>G p.L694= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV58540442; called by muse, mutect2, varscan2
- SUPT6H | c.954C>T p.D318= | Silent (SNP) | VAF 68/677 reads (10%) | catalogued as COSV100112210; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502711 C>G | 5'Flank (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23316G>A | Intron (SNP) | VAF 32/80 reads (40%) | catalogued as rs751411472, COSV59385787; called by muse, mutect2, varscan2
